Surgical pathology report (de-identified scan), TCGA case TCGA-61-2012, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2012-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –

ADIPOSE TISSUE WITH REACTIVE LYMPHOID AGGREGATES, NO NEOPLASM IDENTIFIED.

PART 2: ADNEXA, LEFT, SALPINGO-OOPHORECTOMY –

- A. POORLY DIFFERENTIATED ADENOCARCINOMA OF LEFT OVARY, PREDOMINANTLY PAPILLARY SEROUS TYPE WITH AREAS OF CLEAR CELL AND ENDOMETRIOID CARCINOMA, 18 CM.
- B. NEOPLASM EXTENDS THROUGH OVARIAN CAPSULE AND ONTO THE SURFACE.
- C. LYMPHOVASCULAR INVASION IDENTIFIED.
- D. PATHOLOGIC STAGE: pT2c, NX, MX.
- E. UNREMARKABLE FALLOPIAN TUBE.

PART 3: UTERUS (92 GRAMS) WITH RIGHT ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY –

- A. UNREMARKABLE CERVIX.
- B. CYSTIC ATROPHY OF ENDOMETRIUM.
- C. ADENOMYOSIS.
- D. MICROSCOPIC LEIOMYOMA.
- E. RIGHT OVARY WITH MICROSCOPIC ADENOFIBROMA.
- F. UNREMARKABLE RIGHT FALLOPIAN TUBE.

PART 4: NODULE VESICOUTERINE REFLECTION –

INVASIVE PAPILLARY SEROUS ADENOCARCINOMA.

PART 5: NODULE, BLADDER REFLECTION –

PAPILLARY SEROUS ADENOCARCINOMA IN FIBROUS TISSUE.

PART 6: APPENDIX, APPENDECTOMY –

UNREMARKABLE APPENDIX.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Left
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 18 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Moderately differentiated (6-7 pts)
ARCHITECTURAL PATTERN:	Glandular (1)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	10-24 (2)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SIZE:	< 2 cm.
ASSOCIATED OTHER LESION:	Other lesion(s) Adenofibroma
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIC
Comment:	The capsule was not grossly ruptured but neoplasm extends through the capsule and onto the ovarian surface.

Source: NCI Genomic Data Commons file 5317e468-a14b-40b8-8ba5-3c298e8b7c95 (TCGA-61-2012.534E3236-B9E7-4B0B-A2A3-2FC3A96FAC81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).